Somatic mutation profile of cancer-model specimen HCM-CSHL-0063-C18-85A (3D Organoid; aliquot HCM-CSHL-0063-C18-85A-01D-A768-36), derived from the primary tumor of HCMI case HCM-CSHL-0063-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 75.1 years (27,438 days).
Specimen HCM-CSHL-0063-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8b08e8c-4e22-4256-8d47-c79fb564e74c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0063-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0063-C18-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88c9a347-f590-48c2-85b6-62ba5479b8a6

The open-access MAF lists 159 somatic variants for this specimen: 115 protein-altering or splice-affecting, 25 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 25, Intron 10, Nonsense Mutation 6, Frame Shift Del 5, 5'UTR 3, Frame Shift Ins 2, 5'Flank 2, 3'UTR 2, Nonstop Mutation 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 225/472 reads (48%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, varscan2
- EVC | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 165/377 reads (44%) | catalogued as rs121908425, CM000508; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 305/473 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 214/461 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs766882748, COSV53151095; called by muse, mutect2, varscan2
- ADAMTS9 | c.3967C>T p.R1323C | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs561679926, COSV55779122; called by muse, mutect2, varscan2
- ADGRA1 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1395747433; called by muse, mutect2, varscan2
- ADRA2A | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748646629, COSV54526796, COSV54529199; called by muse, mutect2, varscan2
- APC | c.4325del p.P1442Lfs*31 | Frame Shift Del (DEL) | VAF 78/174 reads (45%) | catalogued as COSV57328830; called by mutect2, pindel, varscan2
- ATP8A2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 71/178 reads (40%) | catalogued as rs759057352, COSV54947743; called by muse, mutect2, varscan2
- BOP1 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 366/711 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1184030561, COSV58189895; called by muse, mutect2, varscan2
- C2CD4C | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs941101868; called by muse, mutect2, varscan2
- C6 | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs752169165; called by muse, mutect2, varscan2
- CARD11 | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 107/221 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs773909937, COSV62754978, COSV62755085; called by muse, mutect2, varscan2
- CCAR1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs748256307, COSV56268129, COSV56268161; called by muse, mutect2, varscan2
- CEACAM3 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs782766786; called by muse, mutect2, varscan2
- COL11A1 | c.1696G>T p.V566F | Missense Mutation (SNP) | VAF 144/144 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV62185294; called by muse, varscan2
- COL22A1 | c.3935G>T p.G1312V | Missense Mutation (SNP) | VAF 243/592 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57345176; called by muse, mutect2, varscan2
- COL5A2 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 171/363 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs766179958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSZ | c.530_531del p.K177Rfs*47 | Frame Shift Del (DEL) | VAF 29/162 reads (18%) | catalogued as rs748290967; called by mutect2, pindel, varscan2
- CTU1 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as rs1026519079; called by muse, mutect2, varscan2
- CYB5D1 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 63/63 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54683606; called by muse, mutect2, varscan2
- DDX3Y | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); catalogued as rs867970646; called by muse, mutect2, varscan2
- EIF4A2 | c.939T>G p.D313E | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs748724172; called by muse, mutect2, varscan2
- FANCG | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 71/517 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372854981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 181/182 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1165902550, COSV67882453; called by muse, mutect2, varscan2
- FBXL7 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 136/305 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs375930592; called by muse, mutect2, varscan2
- FBXO38 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs771708027, COSV57025597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FER1L6 | c.3947G>A p.R1316Q | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs770709548, COSV67551235; called by muse, mutect2, varscan2
- FGF3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782801923; called by muse, mutect2, varscan2
- FMO1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 100/203 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs28360433; called by muse, mutect2, varscan2
- FNDC1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778194307; called by muse, mutect2, varscan2
- GABBR2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs978945843, COSV52309784; called by muse, mutect2, varscan2
- GNAS | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 126/371 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs777234998, COSV58348517; called by muse, mutect2, varscan2
- GPHB5 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs191071731; called by muse, mutect2, varscan2
- HMCN1 | c.9887G>A p.R3296Q | Missense Mutation (SNP) | VAF 118/291 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs771635945, COSV99628838; called by muse, mutect2, varscan2
- IGHE | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 129/264 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs782245796; called by muse, mutect2, varscan2
- ITIH5 | c.1859C>A p.S620Y | Missense Mutation (SNP) | VAF 72/365 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV53667627; called by muse, mutect2, varscan2
- KIAA0825 | c.3012dup p.F1005Ifs*3 | Frame Shift Ins (INS) | VAF 40/99 reads (40%) | catalogued as rs776803745; called by mutect2, varscan2
- KPTN | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 110/205 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1193041866; called by muse, mutect2, varscan2
- LTF | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750868282; called by muse, mutect2, varscan2
- MARCO | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs376695698; called by muse, mutect2, varscan2
- MICAL3 | c.3958C>T p.R1320W | Missense Mutation (SNP) | VAF 83/84 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs768258471, COSV71588742; called by muse, mutect2, varscan2
- MRGPRX1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs567589026, COSV57107622; called by muse, mutect2, varscan2
- MYO9B | c.5378G>A p.R1793Q | Missense Mutation (SNP) | VAF 126/229 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs764277555; called by muse, mutect2, varscan2
- NINL | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 90/189 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs762025575; called by muse, mutect2, varscan2
- OR2T12 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 157/505 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs764836025, COSV58776972; called by muse, varscan2
- OTOG | c.4147G>A p.E1383K | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV61131390; called by muse, mutect2, varscan2
- OTUB1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 249/539 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1254707597, COSV55357778, COSV99735819; called by muse, mutect2, varscan2
- PCDHA1 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 362/701 reads (52%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs782810018; called by muse, mutect2, varscan2
- PCDHA10 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 614/1238 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as COSV100251756; called by muse, mutect2, varscan2
- PCSK1 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 304/686 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1460160220; called by muse, mutect2, varscan2
- PKD1L1 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200343133, COSV56963991, COSV99221622; called by muse, mutect2, varscan2
- PXMP4 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 126/409 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs773129070; called by muse, mutect2, varscan2
- RILPL1 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 146/295 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65300938; called by muse, mutect2, varscan2
- RTL1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV101128316; called by muse, mutect2, varscan2
- SALL1 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 269/270 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs997918353; called by muse, mutect2, varscan2
- SEMA3D | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 248/400 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs749668447, COSV52393626; called by muse, mutect2, varscan2
- SEMA4B | c.1555G>C p.V519L | Missense Mutation (SNP) | VAF 131/255 reads (51%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.918); catalogued as rs751639413; called by muse, mutect2, varscan2
- SEPTIN4 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 192/192 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs371900167; called by muse, mutect2, varscan2
- SIAH3 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 362/872 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs762491862, COSV68551972; called by muse, mutect2, varscan2
- SIGLECL1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1222802505, COSV57061964; called by muse, mutect2, varscan2
- SLIT3 | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60632092; called by muse, mutect2
- SP140 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 75/167 reads (45%) | catalogued as rs143791311; called by muse, mutect2, varscan2
- SSC5D | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 128/628 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs1264232309; called by muse, mutect2, varscan2
- THBD | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV65702374; called by muse, mutect2, varscan2
- TIAM1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as rs771808182, COSV99735379; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 306/408 reads (75%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TRPS1 | c.1748A>G p.Y583C (on ENST00000220888 / NM_001330599.2; = p.Y596C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 172/669 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as CD134240; called by muse, mutect2, varscan2
- TTN | c.2735G>A p.R912H (on ENST00000591111; = p.R866H on NM_003319.4) | Missense Mutation (SNP) | VAF 215/423 reads (51%) | PolyPhen benign (0.003); catalogued as rs766770644; called by muse, mutect2, varscan2
- ZUP1 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs772146000; called by muse, mutect2, varscan2
- ADAM19 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHCYL2 | c.1397T>G p.L466W | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AHNAK2 | c.6313G>T p.V2105L | Missense Mutation (SNP) | VAF 398/1083 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- APC | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 181/402 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARRDC2 | c.372C>A p.H124Q | Missense Mutation (SNP) | VAF 153/299 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASP2 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 113/338 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC18 | c.248del p.N83Tfs*38 | Frame Shift Del (DEL) | VAF 31/45 reads (69%) | called by mutect2, pindel, varscan2
- COL4A5 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSPG4 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 90/145 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CYP1B1 | c.1430A>C p.K477T | Missense Mutation (SNP) | VAF 261/556 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DHX30 | c.1801C>T p.R601* (on ENST00000445061 / NM_138615.3; = p.R562* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 145/326 reads (44%) | called by muse, mutect2, varscan2
- DPY19L2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- DTL | c.2191T>C p.*731Qext*4 | Nonstop Mutation (SNP) | VAF 77/151 reads (51%) | called by muse, mutect2, varscan2
- EIF4G2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- EVI2A | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR149 | c.516G>T p.W172C | Missense Mutation (SNP) | VAF 230/453 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPX6 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- HDAC9 | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 74/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ICE1 | c.5312G>A p.G1771E | Missense Mutation (SNP) | VAF 183/405 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITCH | c.749C>T p.P250L (on ENST00000262650 / NM_001257137.3; = p.P209L on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/566 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- KIF21B | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 123/266 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LHX1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- MGAT5 | c.273dup p.N92* | Frame Shift Ins (INS) | VAF 73/181 reads (40%) | called by mutect2, pindel, varscan2
- NBEA | c.5641A>T p.N1881Y | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- NFATC2IP | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- NLGN4X | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 292/302 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NME8 | c.1741C>A p.L581I | Missense Mutation (SNP) | VAF 121/267 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NPIPB11 | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 160/598 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- PNLIPRP3 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PTPRJ | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RASGRP1 | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 109/210 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- REXO4 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 131/468 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ROBO1 | c.84T>G p.I28M | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SACS | c.5945G>T p.G1982V | Missense Mutation (SNP) | VAF 121/244 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- SLC30A1 | c.1263del p.F421Lfs*4 | Frame Shift Del (DEL) | VAF 89/214 reads (42%) | called by mutect2, pindel, varscan2
- SYNE1 | c.5837C>A p.T1946N (on ENST00000367255 / NM_182961.4; = p.T1953N on NM_033071.3) | Missense Mutation (SNP) | VAF 247/540 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, varscan2
- SYNE1 | c.5202G>A p.M1734I (on ENST00000367255 / NM_182961.4; = p.M1741I on NM_033071.3) | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2
- TAF15 | c.1492C>T p.R498* (on ENST00000605844 / NM_139215.3; = p.R495* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 424/430 reads (99%) | called by muse, mutect2, varscan2
- TDRD3 | c.1931A>G p.Y644C | Missense Mutation (SNP) | VAF 166/309 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM70 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 183/285 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- VGF | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- VTI1A | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 120/276 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ZBBX | c.1725G>T p.L575= | Splice Region (SNP) | VAF 20/39 reads (51%) | called by muse, varscan2
- ZNF548 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ZNF729 | c.2192A>T p.K731M | Missense Mutation (SNP) | VAF 206/474 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- BCO1 | c.1521C>T p.V507= | Silent (SNP) | VAF 221/476 reads (46%) | catalogued as rs760137851, COSV50730287; called by muse, varscan2
- CD22 | c.117C>T p.C39= | Silent (SNP) | VAF 173/335 reads (52%) | catalogued as rs750364404, COSV50071519; called by muse, mutect2, varscan2
- CFP | c.18G>A p.A6= | Silent (SNP) | VAF 103/286 reads (36%) | catalogued as rs1020912849; ClinVar: likely benign; called by muse, mutect2, varscan2
- CR1 | c.3297C>T p.S1099= | Silent (SNP) | VAF 467/984 reads (47%) | catalogued as COSV65465131; called by muse, mutect2, varscan2
- CYP17A1 | c.702C>T p.S234= | Silent (SNP) | VAF 111/251 reads (44%) | catalogued as rs146311005; called by muse, mutect2, varscan2
- DHX34 | c.2445C>T p.P815= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs770947952; called by muse, mutect2, varscan2
- DMRTB1 | c.807G>A p.P269= | Silent (SNP) | VAF 226/228 reads (99%) | catalogued as rs533549553, COSV101008378; called by muse, mutect2, varscan2
- EFCAB12 | c.954G>A p.T318= | Silent (SNP) | VAF 137/276 reads (50%) | catalogued as rs374245278, COSV58177268; called by muse, mutect2, varscan2
- FANCD2OS | c.69G>A p.T23= | Silent (SNP) | VAF 64/121 reads (53%) | catalogued as rs1369877103; called by muse, mutect2, varscan2
- FREM3 | c.5826C>T p.Y1942= | Silent (SNP) | VAF 44/172 reads (26%) | called by muse, mutect2, varscan2
- GJC2 | c.507G>A p.A169= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as rs1455432608; called by muse, varscan2
- HRNR | c.2097C>T p.S699= | Silent (SNP) | VAF 423/903 reads (47%) | catalogued as rs764048595, COSV100912917; called by muse, mutect2, varscan2
- IGDCC4 | c.585C>T p.G195= | Silent (SNP) | VAF 89/182 reads (49%) | catalogued as rs776431286; called by muse, mutect2, varscan2
- KCNC2 | c.240C>T p.G80= | Silent (SNP) | VAF 171/337 reads (51%) | catalogued as rs1174433701, COSV54371889, COSV54376401; called by muse, mutect2, varscan2
- LIPG | c.714C>T p.H238= | Silent (SNP) | VAF 235/236 reads (100%) | catalogued as COSV99724727; called by muse, mutect2, varscan2
- LPAR1 | c.780G>T p.V260= | Silent (SNP) | VAF 20/86 reads (23%) | called by muse, varscan2
- MIER2 | c.1005C>T p.G335= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs773640885; called by muse, mutect2, varscan2
- MKI67 | c.810C>T p.Y270= | Silent (SNP) | VAF 120/272 reads (44%) | catalogued as rs201621002, COSV64072423; called by muse, mutect2, varscan2
- MUC16 | c.24909C>T p.G8303= | Silent (SNP) | VAF 148/290 reads (51%) | called by muse, mutect2, varscan2
- MYT1L | c.2136G>A p.T712= | Silent (SNP) | VAF 147/603 reads (24%) | called by muse, mutect2, varscan2
- NBL1 | c.519C>T p.H173= | Silent (SNP) | VAF 52/52 reads (100%) | called by muse, mutect2, varscan2
- PCDH1 | c.1824T>C p.N608= | Silent (SNP) | VAF 149/330 reads (45%) | catalogued as rs1428280111; called by muse, mutect2, varscan2
- PCDHA1 | c.141C>T p.R47= | Silent (SNP) | VAF 209/441 reads (47%) | called by muse, mutect2, varscan2
- PDIA5 | c.117G>A p.L39= | Silent (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2, varscan2
- RBFOX1 | c.1119T>C p.D373= | Silent (SNP) | VAF 210/210 reads (100%) | called by muse, mutect2, varscan2
- AC002428.1 | chr5:135922365 G>A | 5'Flank (SNP) | VAF 52/127 reads (41%) | catalogued as rs551085108; called by muse, mutect2, varscan2
- ANKRD24 | c.37-1211C>A | Intron (SNP) | VAF 55/100 reads (55%) | catalogued as rs1423890855; called by muse, mutect2, varscan2
- ARPC3 | c.*210C>T | 3'UTR (SNP) | VAF 98/213 reads (46%) | catalogued as rs1288239534; called by muse, mutect2, varscan2
- ASPH | c.323-11773G>A | Intron (SNP) | VAF 57/222 reads (26%) | called by muse, mutect2, varscan2
- ATRNL1 | c.3795+48167C>T | Intron (SNP) | VAF 108/199 reads (54%) | catalogued as rs782186399; called by muse, mutect2, varscan2
- CHRNA4 | c.-41C>T | 5'UTR (SNP) | VAF 157/460 reads (34%) | called by muse, mutect2, varscan2
- DEFB119 | c.61+1368A>C | Intron (SNP) | VAF 175/591 reads (30%) | called by muse, mutect2, varscan2
- EGFLAM | c.2796-18dup | Intron (INS) | VAF 46/129 reads (36%) | called by mutect2, pindel, varscan2
- LY6K | c.-75C>T | 5'UTR (SNP) | VAF 134/219 reads (61%) | catalogued as rs1554639905; called by muse, mutect2, varscan2
- MAMLD1 | c.*690C>T | 3'UTR (SNP) | VAF 39/39 reads (100%) | catalogued as rs927968522; called by muse, mutect2, varscan2
- NUMBL | c.249+38A>G | Intron (SNP) | VAF 76/180 reads (42%) | catalogued as rs1023122970; called by muse, varscan2
- PGAM5P1 | chr5:109884450 C>A | 3'Flank (SNP) | VAF 140/405 reads (35%) | called by muse, mutect2, varscan2
- PLA2G6 | c.210-2970A>T | Intron (SNP) | VAF 48/91 reads (53%) | called by muse, mutect2, varscan2
- POLR1C | c.806-20dup | Intron (INS) | VAF 76/340 reads (22%) | catalogued as rs1171110573; called by mutect2, varscan2
- PRKN | c.1083+3420G>T | Intron (SNP) | VAF 89/181 reads (49%) | catalogued as COSV100627049, COSV58273856; called by muse, mutect2, varscan2
- SNORD115-9 | chr15:25182371 G>C | 5'Flank (SNP) | VAF 74/313 reads (24%) | called by muse, mutect2, varscan2
- SREK1 | c.-174T>C | 5'UTR (SNP) | VAF 69/130 reads (53%) | catalogued as rs1255639147, COSV52333286; called by muse, mutect2, varscan2
- SSPOP | n.10406G>A | RNA (SNP) | VAF 103/187 reads (55%) | called by muse, mutect2, varscan2
- TRIM9 | c.1604-3986G>A | Intron (SNP) | VAF 21/41 reads (51%) | catalogued as rs1444297391, COSV53625689; called by muse, mutect2, varscan2
